Gene-level copy-number profile of tumor specimen TCGA-58-8393-01A from TCGA case TCGA-58-8393, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.8 years (25,132 days).
Specimen TCGA-58-8393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3b9991e1-ed9c-439a-bffe-8f3ef5717c22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-8393-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26b91d7b-43f4-4d6f-92fc-8f342f6d113d

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 24,453; copy number 2: 24,248; copy number 3: 6,562; copy number 4: 4,557.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-8393-01A-11D-2322-01): tumor purity 0.3, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 11,119 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 4 (broad region; genes not listed).
- chr3:75,906,695–77,649,964, 1 gene, copy number 4 (within-gene range 1–4): ROBO2.
- chr3:77,092,057–198,222,513, 1,889 genes, copy number 3–4 (broad region; genes not listed).
- chr6:167,607–67,998,751, 1,579 genes, copy number 3 (broad region; genes not listed).
- chr8:87,540,835–145,066,685, 909 genes, copy number 3 (broad region; genes not listed).
- chr14:86,905,778–102,774,791, 442 genes, copy number 3 (broad region; genes not listed).
- chr15:19,878,555–101,933,350, 2,215 genes, copy number 3 (broad region; genes not listed).
- chr17:39,401,793–73,092,712, 1,129 genes, copy number 3 (broad region; genes not listed).
- chr19:28,435,388–38,426,305, 351 genes, copy number 4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,453. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
